Somatic mutation profile of tumor specimen TCGA-4V-A9QX-01A (aliquot TCGA-4V-A9QX-01A-11D-A423-09) from TCGA case TCGA-4V-A9QX, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 77.3 years (28,250 days).
Specimen TCGA-4V-A9QX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33409588-e333-4083-a1e9-14e5383714c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4V-A9QX-11A (Solid Tissue Normal), aliquot TCGA-4V-A9QX-11A-21D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3ab6800-c0a7-4cea-b592-22999634d50e

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 7, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 28/498 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- AAR2 | c.878C>G p.T293S | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITSN2 | c.3379C>G p.H1127D | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.031); called by muse, mutect2
- OGFRL1 | c.867C>A p.D289E | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.695); called by muse, mutect2
- SLITRK4 | c.436A>G p.I146V | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- ZBTB10 | c.727A>T p.M243L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZDBF2 | c.2347T>C p.C783R | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- BIRC6 | c.36T>A p.T12= | Silent (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- DNAH11 | c.11505C>T p.A3835= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as rs762186712; called by muse, mutect2, varscan2
- FAM120C | c.3228T>C p.N1076= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs782577967; called by muse, mutect2, varscan2
- GFUS | c.816T>C p.D272= | Silent (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- IL16 | c.1209C>T p.D403= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs374076985, COSV57263914; called by muse, mutect2, varscan2
- PKMYT1 | c.1239G>A p.P413= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs376585568; called by mutect2, varscan2
- SPHKAP | c.1800C>T p.P600= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs1229328646; called by muse, mutect2, varscan2
- GNA12 | c.526-29190C>T | Intron (SNP) | VAF 14/103 reads (14%) | called by muse, mutect2, varscan2
